EXCEPTIONAL_RESPONDERS case ER-AD3B — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/40fc5b98-bbd5-419e-a83a-e666bdb23728

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Year of birth: 1952; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 57.4 years (20,981 days); Year of diagnosis: 2009; AJCC staging edition: 7th; AJCC clinical stage: Stage IV; Prior malignancy: no; Days to last follow up: 2,179 days (6.0 years); Days to best overall response: 387 days (1.1 years); Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Cyclophosphamide + Docetaxel; Days to treatment start: 41 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Zoledronic Acid; Days to treatment start: 41 days.
   Treatment given: Therapeutic agents: Anastrozole; Days to treatment start: 141 days.

Follow-up (1 entry)
- Days to follow up: 2,179 days (6.0 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 2,179 days (6.0 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AD3B-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-AD3B-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 24; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 8.
